Gene-level copy-number profile of tumor specimen TCGA-FD-A43Y-01A from TCGA case TCGA-FD-A43Y, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 65.4 years (23,889 days).
Specimen TCGA-FD-A43Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fb6c67c9-d7d8-45fc-9bdc-53bc4f059e01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A43Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80e4507f-2d06-44c7-9179-868a265c6421

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 12,821; copy number 2: 39,221; copy number 3: 5,764; copy number 4: 1,061; copy number 5: 195; copy number 6: 240; copy number 7: 87; copy number 8: 4; copy number 9: 131; copy number 10: 149; copy number 11: 58; copy number 13: 33; copy number 14: 11; copy number 15: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A43Y-01A-21D-A26L-01): tumor purity 0.44, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,455,740, 10 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr18:36,187,497–36,272,157, 1 gene (within-gene range 0–2): MOCOS.
- chr18:36,273,574–36,780,055, 4 genes (within-gene range 0–2): AC023043.2, AC023043.3, FHOD3, AC055840.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 937 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,433,492–42,335,877, 200 genes, copy number 5–13 (within-gene range 1–13) (broad region; genes not listed).
- chr1:42,456,117–42,657,190, 6 genes, copy number 7 (within-gene range 2–7): PPCS, CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1.
- chr1:52,726,453–56,715,335, 111 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr1:56,994,778–65,232,145, 125 genes, copy number 8–9 (broad region; genes not listed).
- chr1:73,305,609–78,369,464, 79 genes, copy number 6–15 (within-gene range 1–15) (broad region; genes not listed).
- chr1:78,317,157–78,317,263, 1 gene, copy number 6: AC096531.1.
- chr3:9,929,852–10,977,981, 35 genes, copy number 5 (within-gene range 2–5): AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13, ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11, AC027128.1.
- chr4:58,780,626–62,165,554, 24 genes, copy number 6 (within-gene range 3–6): AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17.
- chr4:67,701,209–68,080,952, 1 gene, copy number 6 (within-gene range 3–6): UBA6-AS1.
- chr4:67,909,395–76,802,426, 202 genes, copy number 6 (broad region; genes not listed).
- chr6:107,867,756–112,617,880, 117 genes, copy number 5 (broad region; genes not listed).
- chr18:39,206,917–39,800,322, 1 gene, copy number 7 (within-gene range 2–7): MIR924HG.
- chr18:39,622,123–45,068,510, 35 genes, copy number 7–14 (within-gene range 2–14): MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1.

Autosomal genes at a single copy (total copy number 1): 10,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
